Somatic mutation profile of tumor specimen MP2PRT-PAUKIA-TMP1-A (aliquot MP2PRT-PAUKIA-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PAUKIA, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.6 years (2,413 days).
Specimen MP2PRT-PAUKIA-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc99f1d0-2efa-45ed-9c49-1bb9a900aed6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUKIA-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUKIA-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2cf22ed-7ff1-4048-a4ac-8d1b49de3d44

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 5, Silent 4, Frame Shift Ins 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPFIA2 | c.2485G>T p.G829* | Nonsense Mutation (SNP) | VAF 128/309 reads (41%) | catalogued as COSV100333146; called by muse, mutect2, varscan2
- SALL3 | c.3521G>A p.R1174H | Missense Mutation (SNP) | VAF 328/756 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs955277573, COSV73305807; called by muse, mutect2, varscan2
- STAG1 | c.1229A>G p.N410S | Missense Mutation (SNP) | VAF 119/273 reads (44%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs141146689; called by muse, mutect2, varscan2
- ETV6 | c.75_76insCCCG p.S26Pfs*41 | Frame Shift Ins (INS) | VAF 142/356 reads (40%) | called by mutect2, pindel, varscan2
- IFT140 | c.2578-14_2578-1dup p.E860Sfs*21 | Frame Shift Ins (INS) | VAF 78/248 reads (31%) | called by mutect2, varscan2
- IGHV3-53 | chr14:106592661 CCTCCCCTCACTGTGTCT>GTCCGAC | Missense Mutation (DEL) | VAF 7/37 reads (19%) | called by pindel, varscan2*
- SNIP1 | c.958G>T p.V320F | Missense Mutation (SNP) | VAF 53/353 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- UGT2B15 | c.1165A>C p.I389L | Missense Mutation (SNP) | VAF 179/399 reads (45%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.712); called by muse, mutect2, varscan2
- PAX9 | c.705C>T p.A235= | Silent (SNP) | VAF 62/860 reads (7%) | called by muse, mutect2
- PRR36 | c.2730G>A p.S910= | Silent (SNP) | VAF 86/242 reads (36%) | called by mutect2, varscan2
- SEZ6L2 | c.954G>A p.S318= (on ENST00000308713 / NM_001114099.3; = p.S248= on NM_012410.4) | Silent (SNP) | VAF 96/549 reads (17%) | catalogued as rs374912046, COSV58097133; called by muse, mutect2, varscan2
- TEPSIN | c.21A>G p.L7= | Silent (SNP) | VAF 259/682 reads (38%) | catalogued as rs1238715100; called by muse, mutect2, varscan2
